Somatic mutation profile of tumor specimen TCGA-AK-3440-01A (aliquot TCGA-AK-3440-01A-01D-0966-08) from TCGA case TCGA-AK-3440, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.4 years (21,337 days).
Specimen TCGA-AK-3440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9f359b2-8915-47f3-aa1b-93dc2a9b3f1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3440-10A (Blood Derived Normal), aliquot TCGA-AK-3440-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a78e4dd-6fad-4d94-870b-1b927ebb389c

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Nonsense Mutation 1, In Frame Del 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 48/55 reads (87%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3147G>T p.R1049S | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1567490520; called by muse, mutect2, varscan2
- ASAP1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs754279639, COSV63050648; called by muse, mutect2
- CST9L | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100980932; called by muse, mutect2, varscan2
- ELP4 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776621433; called by muse, mutect2, varscan2
- KIF5A | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV54052551; called by muse, mutect2, varscan2
- LTBP4 | c.4382G>A p.R1461H (on ENST00000308370 / NM_001042544.1; = p.R1424H on NM_003573.2) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs1178129446, COSV99180589; called by muse, mutect2, varscan2
- PRKACB | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65763849; called by muse, mutect2
- SLITRK1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65676591; called by muse, mutect2, varscan2
- TRPM3 | c.3115G>C p.E1039Q (on ENST00000357533 / NM_001366142.2; = p.E882Q on NM_020952.6) | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV62593784; called by muse, mutect2
- ABCC11 | c.3146G>T p.R1049M | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ANXA3 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- BNIP5 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 128/152 reads (84%) | called by muse, mutect2, varscan2
- GEMIN8 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 239/259 reads (92%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF628 | c.483del p.S162Afs*265 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- ZNF79 | c.1019_1033del p.K340_C345delinsS | In Frame Del (DEL) | VAF 56/175 reads (32%) | called by mutect2, pindel, varscan2
- GABRG3 | c.1347C>T p.F449= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as COSV100409378; called by muse, mutect2, varscan2
- HERC2 | c.3453C>T p.L1151= | Silent (SNP) | VAF 70/137 reads (51%) | called by muse, mutect2, varscan2
- MIR92A1 | n.73G>C | RNA (SNP) | VAF 99/120 reads (83%) | called by muse, mutect2, varscan2
